TCGA case TCGA-IR-A3LC — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/58bdcace-0047-456e-a225-68953edafe5e

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 40 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 40.2 years (14,697 days); Year of diagnosis: 2003; Method of diagnosis: Biopsy; AJCC pathologic T: T1b1; AJCC pathologic N: N0; AJCC pathologic M: M0; FIGO stage: Stage IB1; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 48; Lymphatic invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment end: 153 days; Treatment dose: 4,500 cGy; Treatment outcome: Complete Response; Treatment anatomic sites: Primary Tumor Field.

Follow-up (3 entries)
- Days to follow up: 3,333 days (9.1 years); Disease response: Tumor Free.
- Days to follow up: 3,571 days (9.8 years); Disease response: Tumor Free.
- Days to follow up: 3,935 days (10.8 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Current User; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Initial Diagnosis; Weight: 64 kg; Height: 160 cm; BMI: 25.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 3; Pregnancy outcome: Live Birth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-IR-A3LC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 140 mg.
  Slide TCGA-IR-A3LC-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-IR-A3LC-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-IR-A3LC-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 3; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Pregnant at diagnosis: No; Total pregnancy count: 3; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lymph nodes examined: Yes; Lymphovascular invasion: Present; Corpus involvement: Absent.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form 1, Treatment, Radiation therapy info: Radiation therapy dose paraaortic nodes: 0.
- Follow-up form 1, Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent fractions total: 6.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,935 days; disease-specific survival: no event (censored), 3,935 days; disease-free interval: no event (censored), 3,935 days; progression-free interval: no event (censored), 3,935 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-IR-A3LC-01A-11D-A20T-01): tumor purity 0.78, ploidy 2.18, whole-genome doublings 0.
